Somatic mutation profile of tumor specimen C3L-00362-02 (aliquot CPT0002500008) from CPTAC case C3L-00362, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 38.5 years (14,058 days).
Specimen C3L-00362-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90240db9-fd80-45a3-9126-c486541d6faa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00362-31 (Blood Derived Normal), aliquot CPT0002850002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86c8cde0-ec95-4f26-9b44-f2597db44233

The open-access MAF lists 36 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, Nonsense Mutation 3, RNA 2, 3'UTR 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 15/286 reads (5%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 174/269 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 117/361 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 136/175 reads (78%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757713402, COSV53321140; called by muse, mutect2, varscan2
- CYP19A1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 115/340 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377298859; called by muse, varscan2
- DPY19L4 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200781402; called by muse, mutect2, varscan2
- GRIA4 | c.170C>A p.A57E | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT tolerated (0.97); PolyPhen benign (0.006); catalogued as rs1340908282, COSV99031227; called by muse, mutect2, varscan2
- IGHV4-28 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 239/586 reads (41%) | catalogued as rs188757611; called by muse, mutect2, varscan2
- INPP5J | c.2247G>C p.W749C (on ENST00000331075 / NM_001284285.2; = p.W381C on NM_001002837.2) | Missense Mutation (SNP) | VAF 61/362 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53212138; called by muse, mutect2, varscan2
- ITIH5 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as rs1341255668, COSV56902224, COSV56905066; called by muse, mutect2, varscan2
- KCNJ12 | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 74/400 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs140886918, COSV59167868; called by muse, mutect2, varscan2
- SEC16A | c.4936G>A p.A1646T | Missense Mutation (SNP) | VAF 130/283 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209856165; called by muse, mutect2, varscan2
- SH3PXD2A | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 120/319 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758059765; called by muse, mutect2, varscan2
- SULT1C4 | c.704C>G p.S235W | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750911106, COSV55597757; called by muse, mutect2, varscan2
- UTP14A | c.801G>T p.E267D | Missense Mutation (SNP) | VAF 30/444 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV64086235; called by muse, mutect2
- ARPC2 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C2CD5 | c.2025dup p.D676Rfs*8 | Frame Shift Ins (INS) | VAF 38/128 reads (30%) | called by mutect2, pindel, varscan2
- EFCC1 | c.1768C>A p.L590I | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2
- FAM135A | c.1804A>T p.N602Y | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- KDM4E | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- PNRC2 | c.110A>C p.K37T | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- PTPRD | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.584); called by muse, mutect2
- REPIN1 | c.634C>G p.L212V | Missense Mutation (SNP) | VAF 96/250 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF487 | c.546C>A p.Y182* | Nonsense Mutation (SNP) | VAF 58/127 reads (46%) | called by muse, mutect2, varscan2
- ARHGAP27 | c.2049G>A p.S683= (on ENST00000428638 / NM_001282290.1; = p.S342= on NM_199282.3) | Silent (SNP) | VAF 19/402 reads (5%) | catalogued as rs1300180091, COSV100976581; called by muse, mutect2
- BSN | c.5574G>A p.R1858= | Silent (SNP) | VAF 7/104 reads (7%) | catalogued as rs1462422280; called by muse, mutect2
- DICER1 | c.3060G>A p.R1020= | Silent (SNP) | VAF 61/306 reads (20%) | catalogued as rs1060504973; ClinVar: likely benign; called by muse, mutect2, varscan2
- ISM1 | c.1305G>A p.E435= | Silent (SNP) | VAF 88/207 reads (43%) | called by muse, mutect2, varscan2
- PCDH17 | c.3126G>A p.A1042= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as rs534412507, COSV100931621, COSV100931767, COSV64975173; called by muse, mutect2, varscan2
- THAP4 | c.987C>T p.N329= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as rs750010467; called by muse, mutect2, varscan2
- ZNF784 | c.57A>T p.R19= | Silent (SNP) | VAF 26/192 reads (14%) | called by muse, mutect2, varscan2
- CHM | c.314+7241G>A | Intron (SNP) | VAF 25/354 reads (7%) | catalogued as rs1369203673; called by muse, mutect2
- OR3A4P | n.440G>A | RNA (SNP) | VAF 88/188 reads (47%) | catalogued as rs773612096; called by muse, mutect2, varscan2
- SSPOP | n.9799G>A | RNA (SNP) | VAF 16/376 reads (4%) | called by muse, mutect2
- TNFRSF10B | c.*2217G>A | 3'UTR (SNP) | VAF 60/159 reads (38%) | catalogued as rs761845443; called by muse, mutect2, varscan2
